Somatic mutation profile of tumor specimen TCGA-WY-A859-01A (aliquot TCGA-WY-A859-01A-12D-A36O-08) from TCGA case TCGA-WY-A859, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 34.6 years (12,631 days).
Specimen TCGA-WY-A859-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 518d49fb-5c9b-4b76-a42d-3babb0b6e57b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WY-A859-10A (Blood Derived Normal), aliquot TCGA-WY-A859-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/593008e4-081e-4477-ae24-5ce568d90bb1

The open-access MAF lists 30 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 4, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 32/82 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 35/41 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APOO | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.402); catalogued as COSV101004868; called by muse, mutect2, varscan2
- CFAP65 | c.5201C>T p.P1734L | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs1303874872, COSV100444388; called by muse, mutect2, varscan2
- DCP1B | c.686C>G p.T229R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99767069; called by muse, mutect2, varscan2
- HEY2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.806); catalogued as rs769963246, COSV64239865; called by muse, mutect2, varscan2
- HEY2 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100856252; called by muse, mutect2
- HLA-DMA | c.355A>C p.K119Q | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs1418144204, COSV100877641, COSV66385636; called by muse, mutect2, varscan2
- IFNA6 | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101207005, COSV66506471; called by muse, mutect2, varscan2
- LRCH4 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV100052659; called by muse, mutect2, varscan2
- MID1IP1 | c.87C>G p.D29E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100423625; called by muse, mutect2, varscan2
- MRPL38 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99485239; called by muse, mutect2
- MUC16 | c.4324C>T p.P1442S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1289255832, COSV101197349; called by muse, mutect2, varscan2
- N4BP1 | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99284650; called by muse, mutect2, varscan2
- NHS | c.4424G>T p.S1475I | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV66276626; called by muse, mutect2, varscan2
- NUP188 | c.2701T>C p.F901L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101001114; called by muse, mutect2
- OR4D11 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100506439; called by muse, mutect2
- PABPC4 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100790829; called by muse, mutect2, varscan2
- PABPC4 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs777242194, COSV100790830; called by muse, mutect2, varscan2
- RPS6KA1 | c.1888G>A p.G630S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.35); catalogued as rs369721857; called by muse, mutect2, varscan2
- SEC16B | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.121); catalogued as rs902343637, COSV100381107; called by muse, mutect2, varscan2
- TRPC4 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV100155426; called by muse, mutect2, varscan2
- VIP | c.209C>A p.T70K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1425873763, COSV65889778; called by muse, mutect2, varscan2
- ZNF629 | c.2358C>G p.H786Q | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99354470; called by muse, mutect2, varscan2
- EVC2 | c.1723del p.E575Sfs*2 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- ATP7A | c.1146C>T p.N382= | Silent (SNP) | VAF 115/180 reads (64%) | catalogued as COSV58443704; called by muse, mutect2, varscan2
- KRTDAP | c.123C>A p.P41= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100139206; called by muse, mutect2
- NEIL1 | c.132C>G p.A44= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100748475; called by muse, mutect2, varscan2
- SLX4 | c.5208C>T p.G1736= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs569225834, COSV53561971; called by muse, mutect2, varscan2
- OR2W5 | n.397G>A | RNA (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
